Surgical pathology report (de-identified scan), TCGA case TCGA-44-6146, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6146-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Level 9 node
- B. Level 10 node
- C. Level 11 node
- D. Left lower lobe
- E. Level 5 node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung lesion, rule out cancer

POST-OP DIAGNOSIS: Diagnosis: lung lesion.

FROZEN SECTION DIAGNOSIS

lower lobe, lobectomy - Mucinous adenocarcinoma.

lobe, bronchial margin - No tumor seen.

GROSS DESCRIPTION

A. Received fresh labeled "level 9 node" is a 1.2 cm in greatest dimension mucoid-appearing dusky gray-black tissue

in keeping with lymph node which is bisected and entirely submitted in one block.

B. Received fresh labeled "level 10 node" are three fragmented, markedly cauterized gray-black tissues ranging from 0.1 to 1.0 cm in greatest dimension which are submitted in toto.

C. Received fresh labeled "level 11 node" are two rubbery tan-red to gray-black tissues in keeping with lymph nodes measuring 0.35 cm in greatest dimension and 1.2 x 0.6 x 0.4 cm.

The larger tissue is bisected and the specimens are entirely submitted in two blocks as labeled.

BLOCK S A 1 - Bisected larger tissue; 2 - smaller tissue in toto.

D. Received fresh labeled "left lower lobe" it is a single

[page 2 of 3]
[REDACTED]

piece of lung tissue measuring 25 x 18 x 10 cm in greatest dimensions. The pleural surface is focally puckered. Ink is applied at the pleural surface of the specimen is serially sectioned. On cut section the lung consists of firm tan gelatinous/mucinous tissue which measures 21 x 14 x 10 cm in greatest dimensions. Only a thin rim of peripheral uninvolved lung tissue is present. The firm tan tissue does not extend to involve the tissue surrounding the bronchial margin. RS: DFS1 and DFS2: Representative sections of lung tissue, DFS 3 bronchial margin, D1-D13: sections of lung lesion, (D4 and D5: pleural puckering) D14 - uninvolved lung, D15 - possible nodes.

E. Received fresh labeled "level 5 node" are four soft gray-black tissues ranging from . 0 c n greatest dimension which are submitted in toto. [REDACTED] - [REDACTED] [REDACTED]: [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A. Sections of the level 9 node demonstrate no evidence of metastasis in one lymph node.
B. The level 10 lymph node demonstrates 3 lymph nodes with no evidence of metastasis.
C. The level 11 lymph node demonstrates no evidence of metastasis in two lymph nodes.
D. The following template applies to the left lower lobe:
Histologic type: Mucinous adenocarcinoma
Histologic grade: Well-differentiated
Primary tumor: 21 cm (pT3)
Margins of resection: Uninvolved
Pleura: uninvolved
Regional lymph nodes: No evidence of metastasis in 3 lymph nodes on this specimen and 10 additional lymph nodes in specimens A., B., C.
and E. (pN0)
Distant metastasis: Cannot be evaluated by this specimen (pMX).
Other findings: The specimen shows a well differentiated mucinous adenocarcinoma. Much of the specimen demonstrates lepidic growth which is suggestive of a bronchoalveolar carcinoma. Multiple foci of invasion are identified however. Almost the entire lobe of the lung was involved and all sections taken from the 21 cm lesion identified grossly contain mucinous adenocarcinoma.

14, 15X2, 5, 3X4

B. There is no evidence of metastasis in 4 level V lymph nodes.

[page 3 of 3]
DIAGNOSIS

- A. Level 9 lymph node, resection:
- No evidence of metastasis in one lymph node (0/1).
- B. Level 10 lymph nodes, resection:
- No evidence of metastasis in 3 lymph nodes (0/3).
- C. Level 11 lymph nodes, resection:
- No evidence of metastasis in 2 lymph nodes (0/2).
- D. Lung, left lower lobe, lobectomy:
- Mucinous adenocarcinoma, well-differentiated, and 21 cm in greatest - No evidence of metastasis in 3 lymph nodes (0/3).
- Surgical margin uninvolved.
- E. Level 5 lymph nodes, resection:
- No evidence of metastasis in 4 lymph nodes (0/4).
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 7754e8be-fea0-4987-b4c0-ac8f8b7ea339 (TCGA-44-6146.51A479AB-4C21-4189-A682-E6976D509ED3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).